Somatic mutation profile of tumor specimen HCM-WCMC-1287-C67-01A (aliquot HCM-WCMC-1287-C67-01A-15D-A905-36) from HCMI case HCM-WCMC-1287-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Combined small cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 74.8 years (27,327 days).
Specimen HCM-WCMC-1287-C67-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0b7dcf6-bf03-4438-9ab6-7825b5adfd64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1287-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-1287-C67-10A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72962301-b14b-4906-8eda-7a48f4876ad7

The open-access MAF lists 152 somatic variants for this specimen: 113 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 36, Nonsense Mutation 11, Frame Shift Ins 3, Intron 2, Splice Site 2, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPC1 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs483352891, CM146762; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 188/214 reads (88%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV51443682; called by muse, mutect2, varscan2
- ACOXL | c.1544A>G p.Y515C (on ENST00000389811 / NM_001371254.1; = p.Y485C on NM_001142807.4) | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs370944721; called by muse, mutect2, varscan2
- BBS12 | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 144/336 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58562107; called by muse, mutect2, varscan2
- C12orf43 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- CHL1 | c.2071G>T p.E691* (on ENST00000397491 / NM_001253387.1; = p.E707* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 29/303 reads (10%) | catalogued as COSV56593907; called by muse, mutect2, varscan2
- COL6A5 | c.3740C>T p.A1247V | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557597562, COSV55209835; called by muse, mutect2, varscan2
- CRACD | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757293190; called by muse, mutect2, varscan2
- DLL4 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1243523935, COSV51062304; called by muse, mutect2
- DNAH3 | c.6763T>C p.Y2255H | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766728991; called by muse, mutect2, varscan2
- DPY19L3 | c.1993A>G p.M665V | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.874); catalogued as rs199792338; called by muse, mutect2, varscan2
- DSCAML1 | c.4311C>A p.N1437K (on ENST00000321322; = p.N1377K on NM_020693.4) | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs755146000; called by muse, mutect2
- DYSF | c.5495G>A p.G1832E | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765781191, COSV99246065; called by muse, mutect2
- FAT4 | c.5458C>T p.L1820F | Missense Mutation (SNP) | VAF 166/362 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1251905201; called by muse, mutect2, varscan2
- FN1 | c.6550C>T p.R2184W (on ENST00000359671 / NM_001365524.2; = p.R2153W on NM_002026.4) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs760613059; called by muse, mutect2, varscan2
- HNF4G | c.121C>T p.R41C (on ENST00000354370 / NM_001330561.2; = p.R88C on NM_004133.5) | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62966093; called by muse, mutect2, varscan2
- KCNH7 | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59814394; called by muse, mutect2
- KLF4 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs761126579, COSV101012654; called by muse, mutect2, varscan2
- LHCGR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs979633619, COSV54295551, COSV54300568; called by muse, mutect2, varscan2
- LIN28A | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV54261846; called by muse, mutect2, varscan2
- MIDN | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99960482; called by muse, mutect2
- MMAA | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as COSV55581829; called by muse, mutect2, varscan2
- MROH2A | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs866984468, COSV67680924; called by mutect2, varscan2
- MRPS18B | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs759454468; called by muse, mutect2
- MUC17 | c.4789C>A p.P1597T | Missense Mutation (SNP) | VAF 147/294 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV60283878; called by mutect2, varscan2
- MYO15A | c.8917G>A p.A2973T | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.325); catalogued as rs960004024; called by muse, mutect2
- NEBL | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 131/309 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1443675600, COSV101009211; called by muse, mutect2, varscan2
- NIBAN1 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); catalogued as COSV62284224; called by muse, mutect2
- NMBR | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs745694294; called by muse, mutect2, varscan2
- NUCB1 | c.480G>A p.T160= | Splice Region (SNP) | VAF 19/131 reads (15%) | catalogued as rs1345057334, COSV54386942; called by muse, mutect2, varscan2
- OR4K2 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 130/262 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53848214; called by mutect2, varscan2
- PCDHA2 | c.1320C>G p.S440R | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.338); catalogued as rs1554119811; called by muse, mutect2, varscan2
- PELI3 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); catalogued as rs541571878, COSV57856057; called by muse, mutect2, varscan2
- PEX5 | c.1837A>G p.M613V (on ENST00000420616; = p.M605V on NM_000319.5) | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs765623850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD1 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as rs1420215253, COSV65058987; called by muse, mutect2, varscan2
- RANBP9 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 34/522 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs756698498; called by muse, mutect2
- SI | c.4427G>A p.G1476E | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as CM1213018, COSV52274082; called by muse, mutect2, varscan2
- SLC24A5 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1408506794; called by muse, mutect2, varscan2
- SLC27A2 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 148/340 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51062527; called by muse, mutect2, varscan2
- SUPT6H | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs762812168, COSV58931545; called by muse, mutect2
- SYCP2 | c.1130C>A p.S377* | Nonsense Mutation (SNP) | VAF 99/316 reads (31%) | catalogued as COSV62771703; called by muse, mutect2, varscan2
- TNXB | c.3947C>T p.T1316M (on ENST00000647633; = p.T1069M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs755472309; called by muse, mutect2, varscan2
- WNT5B | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs749761500; called by muse, mutect2, varscan2
- ZBTB32 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1233708222; called by muse, mutect2, varscan2
- ZNF775 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs749944741; called by muse, mutect2, varscan2
- ZNF785 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs934319908; called by muse, mutect2, varscan2
- ACSL1 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM10 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APOLD1 | c.346C>G p.L116V (on ENST00000326765 / NM_001130415.2; = p.L85V on NM_030817.3) | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2
- ATAT1 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BIRC3 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 163/412 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- C8orf82 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.218); called by muse, varscan2
- CCKBR | c.152-1G>A p.X51_splice | Splice Site (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- CELF6 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CEP295 | c.2738C>T p.S913F | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.875); called by muse, mutect2
- CFAP43 | c.137A>T p.N46I | Missense Mutation (SNP) | VAF 120/208 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CHPF2 | c.2037C>G p.Y679* | Nonsense Mutation (SNP) | VAF 121/249 reads (49%) | called by muse, mutect2, varscan2
- CMYA5 | c.9784C>G p.L3262V | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNOT10 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CTPS1 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CYP19A1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYP4F12 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FOXF2 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FRMPD1 | c.1450C>G p.L484V | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- GCC2 | c.5024C>G p.S1675C | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HCN1 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 170/386 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HIRA | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 63/199 reads (32%) | called by muse, mutect2, varscan2
- IGKV1D-43 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 116/256 reads (45%) | called by muse, mutect2, varscan2
- IGLV3-25 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 67/110 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIR3DL3 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, varscan2
- KLF4 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.363); called by muse, mutect2
- KMT2A | c.5016_5035dup p.S1679Kfs*35 | Frame Shift Ins (INS) | VAF 50/165 reads (30%) | called by mutect2, varscan2
- LPIN1 | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by mutect2, varscan2
- M1AP | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 11/286 reads (4%) | called by muse, mutect2
- MAP3K20 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MUC16 | c.8620G>C p.A2874P | Missense Mutation (SNP) | VAF 106/226 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2
- MYO19 | c.520A>T p.N174Y | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- NIN | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 31/187 reads (17%) | called by muse, mutect2, varscan2
- NOM1 | c.1606G>A p.G536S | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OXTR | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- PABPC4 | c.649dup p.T217Nfs*30 | Frame Shift Ins (INS) | VAF 76/180 reads (42%) | called by mutect2, varscan2
- PARP14 | c.2723C>T p.A908V | Missense Mutation (SNP) | VAF 125/226 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH11X | c.95A>C p.E32A | Missense Mutation (SNP) | VAF 179/210 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNX3 | c.4276G>C p.G1426R | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PI4KA | c.4334G>C p.R1445P | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- PLPPR1 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PPP1R3A | c.2026A>G p.I676V | Missense Mutation (SNP) | VAF 208/420 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPP1R9B | c.1549dup p.A517Gfs*31 | Frame Shift Ins (INS) | VAF 90/210 reads (43%) | called by mutect2, varscan2
- PRIMPOL | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.044); called by muse, mutect2
- PRMT5 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASA1 | c.2827C>A p.L943I | Missense Mutation (SNP) | VAF 100/205 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RYR2 | c.8432G>A p.S2811N | Missense Mutation (SNP) | VAF 126/262 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- SAMD1 | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- SCN5A | c.4013T>G p.L1338R (on ENST00000333535 / NM_198056.3; = p.L1337R on NM_000335.5) | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SH3D19 | c.1765G>T p.E589* | Nonsense Mutation (SNP) | VAF 28/398 reads (7%) | called by muse, mutect2
- SLC16A12 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 139/245 reads (57%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.496); called by muse, mutect2
- SLC40A1 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC49A3 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SMG1 | c.1946T>C p.V649A | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SORCS1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- STYXL2 | c.1903C>A p.Q635K | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.012); called by muse, mutect2
- SYTL3 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- TAF4B | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 154/395 reads (39%) | called by muse, mutect2, varscan2
- TCHHL1 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TRAPPC8 | c.1669_1710del p.V557_R570del | In Frame Del (DEL) | VAF 32/180 reads (18%) | called by mutect2, varscan2
- TTYH1 | c.566T>A p.L189Q | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBE2A | c.355A>G p.N119D | Missense Mutation (SNP) | VAF 131/144 reads (91%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- UPP2 | c.893A>C p.Q298P | Missense Mutation (SNP) | VAF 137/278 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UTRN | c.3973del p.X1325_splice | Splice Site (DEL) | VAF 62/157 reads (39%) | called by mutect2, varscan2
- VARS2 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 118/308 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ZFP30 | c.459C>A p.N153K | Missense Mutation (SNP) | VAF 155/301 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF729 | c.2401T>C p.C801R | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2
- ABCB1 | c.264G>A p.L88= | Silent (SNP) | VAF 89/210 reads (42%) | called by muse, mutect2, varscan2
- BAHCC1 | c.4737G>A p.L1579= | Silent (SNP) | VAF 16/191 reads (8%) | called by muse, mutect2
- CD320 | c.411C>T p.L137= | Silent (SNP) | VAF 85/176 reads (48%) | called by muse, mutect2, varscan2
- CDHR4 | c.1956G>A p.R652= | Silent (SNP) | VAF 15/216 reads (7%) | called by muse, mutect2
- CDK11B | c.1254C>G p.L418= | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as rs1046458106; called by muse, mutect2, varscan2
- CLEC16A | c.949C>T p.L317= | Silent (SNP) | VAF 78/292 reads (27%) | called by muse, varscan2
- DNAH5 | c.1707A>G p.L569= | Silent (SNP) | VAF 126/309 reads (41%) | called by muse, mutect2, varscan2
- DSEL | c.2886A>G p.A962= | Silent (SNP) | VAF 171/391 reads (44%) | called by muse, mutect2, varscan2
- GOLGA8M | c.891G>A p.P297= | Silent (SNP) | VAF 109/271 reads (40%) | catalogued as rs1187561670; called by muse, mutect2, varscan2
- IRGQ | c.810G>A p.P270= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as rs776059259; called by muse, mutect2, varscan2
- ITGAV | c.153C>T p.F51= | Silent (SNP) | VAF 40/215 reads (19%) | catalogued as rs1157905919, COSV53710618; called by muse, mutect2, varscan2
- KAT6B | c.1926G>A p.Q642= | Silent (SNP) | VAF 80/234 reads (34%) | called by muse, mutect2, varscan2
- LILRA5 | c.390C>T p.P130= | Silent (SNP) | VAF 105/194 reads (54%) | catalogued as rs756572938; called by muse, mutect2, varscan2
- MRPL14 | c.312C>T p.N104= | Silent (SNP) | VAF 44/216 reads (20%) | catalogued as rs778710647, COSV64394405; called by muse, mutect2
- MUC17 | c.13110G>A p.V4370= | Silent (SNP) | VAF 15/165 reads (9%) | called by muse, mutect2
- NEB | c.15342C>A p.S5114= | Silent (SNP) | VAF 58/160 reads (36%) | called by mutect2, varscan2
- OR2L2 | c.840C>A p.L280= | Silent (SNP) | VAF 26/366 reads (7%) | catalogued as COSV63560792; called by muse, mutect2
- PIEZO2 | c.2043C>T p.A681= | Silent (SNP) | VAF 186/428 reads (43%) | called by muse, mutect2, varscan2
- PIWIL4 | c.1185G>C p.L395= | Silent (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- POLQ | c.834G>A p.L278= | Silent (SNP) | VAF 111/322 reads (34%) | called by muse, mutect2, varscan2
- POR | c.141C>T p.F47= | Silent (SNP) | VAF 30/403 reads (7%) | called by muse, mutect2
- PRB4 | c.639C>A p.P213= | Silent (SNP) | VAF 137/298 reads (46%) | catalogued as rs996264922, COSV54400979; called by muse, mutect2, varscan2
- RIC3 | c.480C>G p.A160= | Silent (SNP) | VAF 120/300 reads (40%) | called by muse, mutect2, varscan2
- RTN4RL1 | c.111G>A p.T37= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as rs781616813; called by muse, mutect2, varscan2
- SIGLEC14 | c.711G>A p.Q237= | Silent (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- SMARCA2 | c.3783G>A p.R1261= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as COSV61806960; called by muse, mutect2, varscan2
- SPATA31D1 | c.4545C>T p.P1515= | Silent (SNP) | VAF 101/229 reads (44%) | called by muse, mutect2, varscan2
- STAMBP | c.441G>A p.Q147= | Silent (SNP) | VAF 61/322 reads (19%) | called by muse, mutect2, varscan2
- SUPT6H | c.1243C>A p.R415= | Silent (SNP) | VAF 27/288 reads (9%) | called by muse, mutect2
- SYNE1 | c.23799G>A p.Q7933= (on ENST00000367255 / NM_182961.4; = p.Q7862= on NM_033071.3) | Silent (SNP) | VAF 32/179 reads (18%) | called by muse, mutect2, varscan2
- TEAD4 | c.738G>A p.L246= | Silent (SNP) | VAF 19/205 reads (9%) | called by muse, mutect2
- TMEM63A | c.1566C>T p.L522= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as rs373734512; called by muse, mutect2, varscan2
- TUBA3D | c.48C>T p.I16= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as rs767332287; called by muse, mutect2
- UCMA | c.84T>C p.S28= | Silent (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- VCAN | c.1578C>T p.I526= | Silent (SNP) | VAF 179/295 reads (61%) | catalogued as rs1410187149, COSV54116141; called by muse, mutect2, varscan2
- ZNF454 | c.153C>G p.V51= | Silent (SNP) | VAF 66/148 reads (45%) | catalogued as COSV100194530, COSV100195199, COSV60770681; called by muse, mutect2, varscan2
- MUCL3 | c.946+1075C>G | Intron (SNP) | VAF 48/461 reads (10%) | catalogued as COSV100424311, COSV58519019; called by muse, mutect2, varscan2
- NBPF25P | n.438C>T | RNA (SNP) | VAF 30/245 reads (12%) | called by muse, mutect2, varscan2
- OSR2 | c.-114-420G>C | Intron (SNP) | VAF 9/254 reads (4%) | called by muse, mutect2
